Gene-level copy-number profile of tumor specimen ALCH-ACG6-TTP1-A from ALCHEMIST case ALCH-ACG6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Large cell carcinoma, NOS; Age at diagnosis: 57.1 years (20,864 days).
Specimen ALCH-ACG6-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2f48a8eb-f656-4a4a-af22-67f84e631afe.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ACG6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,248 have no estimate.
https://portal.gdc.cancer.gov/files/78d39401-76f5-4df6-83a0-c78d6f54b2ca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 39; copy number 1: 8,383; copy number 2: 46,309; copy number 3: 3,301; copy number 4: 186; copy number 5: 49; copy number 6: 104; copy number 7: 3; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 37 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,639,241–10,654,333, 1 gene (within-gene range 0–3): AL139423.1.
- chr1:12,922,554–12,922,660, 1 gene (within-gene range 0–3): RNU6-1072P.
- chr1:44,819,844–44,843,253, 2 genes (within-gene range 0–2): PTCH2, RNU5E-6P.
- chr1:143,720,510–143,739,506, 3 genes: RNVU1-23, RNVU1-18, AC239800.2.
- chr3:52,455,118–52,493,068, 1 gene: NISCH.
- chr4:3,766,348–3,768,526, 1 gene: ADRA2C.
- chr4:118,635,970–118,640,858, 2 genes: CICP16, SEPTIN14P4.
- chr7:44,919,669–44,920,329, 1 gene: AC004854.1.
- chr8:20,551,201–20,551,405, 1 gene: AC022559.1.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–1): CRB2.
- chr9:123,402,525–123,402,603, 1 gene (within-gene range 0–1): MIR601.
- chr9:128,411,751–128,437,351, 2 genes (within-gene range 0–2): CERCAM, AL359091.4.
- chr9:130,172,404–130,237,303, 1 gene: NCS1.
- chr11:67,398,181–67,421,183, 2 genes (within-gene range 0–2): PPP1CA, TBC1D10C.
- chr12:57,194,504–57,194,576, 1 gene (within-gene range 0–2): MIR1228.
- chr13:41,101,019–41,101,100, 1 gene: MIR3168.
- chr17:17,507,351–17,508,308, 1 gene (within-gene range 0–2): AC020558.2.
- chr17:18,087,892–18,110,463, 2 genes (within-gene range 0–1): DRG2, AC087164.2.
- chr18:37,243,776–37,306,333, 3 genes (within-gene range 0–1): AC015961.2, AC090386.1, AC090386.2.
- chr19:19,254,748–19,273,369, 2 genes (within-gene range 0–1): AC138430.1, HAPLN4.
- chr19:19,264,364–19,320,509, 2 genes: TM6SF2, SUGP1.
- chr20:35,588,324–35,588,607, 1 gene (within-gene range 0–2): RPL37P1.
- chr22:22,630,065–22,636,153, 2 genes: BCRP4, AC244250.4.
- chr22:29,705,256–29,719,859, 2 genes (within-gene range 0–2): AC004882.1, AC004882.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 157 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:105,366,909–108,378,285, 36 genes, copy number 5–6: ALCAM, CBLB, AC079382.1, LINC00882, Y_RNA, AC080097.1, Y_RNA, FCF1P3, MTND4P16, MTND4LP3, MTND3P6, MTCO3P35, MTATP6P22, MTND5P16, MTND6P6, MTCO1P35, MTND1P16, MTND2P14, RNU6-1308P, AC117435.1, AC074043.1, DUBR, AC063944.1, CSP2, AC063944.2, CCDC54, LINC01990, BBX, LINC00636, LINC00635, AC012020.1, CD47, LINC01215, IFT57, HHLA2, HNRNPA1P17.
- chr3:123,968,521–125,058,438, 18 genes, copy number 5: ROPN1, KALRN, MIR5002, RPL7P15, MIR6083, RNU6-143P, AC022336.2, UMPS, MIR544B, AC022336.1, ITGB5, ITGB5-AS1, AC022336.3, 7SK, ENO1P3, MUC13, HEG1, RNA5SP137.
- chr3:167,478,684–170,860,993, 66 genes, copy number 6 (within-gene range 2–6) (broad region; genes not listed).
- chr6:32,190,766–32,195,523, 1 gene, copy number 7 (within-gene range 3–7): GPSM3.
- chr14:77,024,543–77,031,572, 2 genes, copy number 7: IRF2BPL, AC007686.3.
- chr16:28,097,976–28,211,965, 4 genes, copy number 5: XPO6, TPRKBP2, AC136611.1, RNY1P10.
- chr17:16,829,999–16,832,830, 1 gene, copy number 20: KRT16P2.
- chr18:42,743,227–45,967,329, 28 genes, copy number 5–6: RIT2, SYT4, AC022743.1, AC083760.1, RNA5SP455, AC110014.1, LINC01478, KRT8P5, MLECP1, SETBP1-DT, SETBP1, AC021766.1, MIR4319, AC105074.1, AC090376.1, SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3, AC091151.2, AC091151.7, AC091151.1, AC023421.1, AC023421.2, SLC14A1, AC087685.1, SIGLEC15, EPG5.
- chr21:43,159,066–43,162,277, 1 gene, copy number 5: AP001631.1.

Autosomal genes at a single copy (total copy number 1): 8,346. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
